National Lung Screening Trial (NLST) participant 202649 — screening results, CT findings and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 11): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 34 cm, reconstruction filter GE Bone / GE Standard.
- T1: No screening result: Not Compliant - Refused a screen.
- T2: No screening result: Not Compliant - Refused a screen.

Abnormalities recorded by the reading radiologist on the CT screens (4 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins spiculated (stellate); predominant attenuation soft tissue; greatest diameter on CT slice 100.
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T0 abnormality 3: Emphysema.
- T0 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer occurred after the screening years; study year of the first confirmed lung cancer: T5; the diagnosis is not linked to a positive screen by the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 1,907, study year T5. Site: upper lobe of lung (ICD-O-3 C34.1), determined from cytology and histology combined. Primary tumour location: left upper lobe, left hilum. Histology: small cell carcinoma, NOS (ICD-O-3 8041/3). Tumour size on pathology: 61 mm. AJCC 6th edition staging: stage IV (best stage, from a mixture of clinical and pathologic TNM components); clinical T3 N3 M1 (stage IV); pathologic TX N3 MX. AJCC 7th edition staging: stage IV; clinical T3 N3 M1b; pathologic TX NX MX. Summary stage: distant. VALCSG stage (the small-cell staging system; ACRIN recorded it for all its lung cancers): extensive.

Follow-up
Last known free of lung cancer: day 1,907 (for ACRIN participants with lung cancer this field holds the diagnosis date).
